Surgical pathology report (de-identified scan), TCGA case TCGA-Q1-A73R, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q1-A73R-01A (Primary Tumor).

[page 1 of 2]
RUN DATE:
RUN TIME:
BY:

PAGE:1

SPEC #:
STATUS:

Obtained:
Received:

Subm Dr:

CLINICAL HISTORY:

STAT, ICD-180.0

SPECIMEN/PROCEDURE:

1. CERVICAL BIOPSY
2. ENDOMETRIAL BX

ICD-O-3
Adenocarcinoma, endocervical type
888413
Site Correl NOS
C53.9
QW8/15/13

IMPRESSION:

1) CERVIX, BIOPSY:

- . Invasive adenocarcinoma, compatible with usual endocervical type; moderately differentiated; see important comment.
- . Lymphovascular invasion is not identified.

2) ENDOMETRIUM, BIOPSY:

- . Scant fragments of carcinoma; see diagnosis #1 above.
- . Separate fragments of atrophic endometrium.

Dictated by:

Entered:

COMMENT:

The cervical biopsy (#1) shows fragments of gland-forming adenocarcinoma admixed with fragments of carcinoma with solid non-glandular growth pattern and high mitotic rate. Some of the fragments may contain a component of endocervical adenocarcinoma in situ; the degree of back-to-back glandular confluency in one of the fragments, however, is diagnostic of invasive adenocarcinoma. Both the gland-forming and solid components of tumor show strong immunoreactivity for p16 compatible with endocervical primary. The solid mitotically active component shows no evidence of immunoreactivity for neuroendocrine markers (chromogranin, synaptophysin, CD56), stains positive for pan-keratin and CK7, and stains negative for cytokeratin 5/6. These findings suggest that the solid component may represent a poorly differentiated component of the adenocarcinoma and rule against a small cell neuroendocrine or invasive squamous carcinoma component.

Representative H&E sections reviewed by

Case discussed with

on

Entered:

SPECIAL STAINS/PROCEDURES:

The following immunohistochemical stains are performed with appropriate positive and negative controls:

p16:

Strong diffuse staining within glandular and solid components of tumor.

Pan-Keratin:

** CONTINUED ON NEXT PAGE **

[page 2 of 2]
SPECIAL STAINS/PROCEDURES: (continued)

Strong diffuse staining within glandular and solid components of tumor.

Cytokeratin 8/18:

Strong diffuse staining within glandular and solid components of tumor.

Cytokeratin 5/6:

Predominantly negative in tumor, but with patchy apical membranous staining in gland forming component; negative in solid component of tumor.

Chromogranin:

Negative staining in tumor.

Synaptophysin:

Negative staining in tumor.

CD56:

Negative staining in tumor.

Dictated by:

GROSS DESCRIPTION:

1. Received in formalin labeled '...' and with the patient's name, the specimen consists of multiple fragments of pale tan tissue intermixed with a moderate amount of clotted blood measuring 2 x 1.6 x 0.6 cm in aggregate. The specimen is filtered and entirely submitted in one cassette.

2. Received in formalin labeled '...' and with the patient's name, the specimen consists of multiple minute pale tan tissue fragments intermixed with a scant amount of clotted blood measuring 2 x 0.7 x 0.2 cm in aggregate. The specimen is filtered and entirely submitted in one cassette.

Dictated by:

Entered:

COPIES TO:

CPT Codes:

IHC CK818-88342, IHC CHROMAGRANIN-88342, IHC SYNAPTOPHYSIN-88342,
ENDOMETRIAL BX/CURETTING/88305, IHC KERATIN COCKTAIL-88342, IHC P16-88342, IHC CD56-88342,
IHC CYTOKERATIN 5/6-88342, CERVICAL BIOPSY/88305, NEG MAB CONTROL

ICD9 Codes:

180.0

Electronically Signed by:

**** END OF REPORT ****

Source: NCI Genomic Data Commons file 65773181-16d7-4358-bd28-317b0ff3f7ec (TCGA-Q1-A73R.2294E1F2-FA18-4E80-A7C8-F7089B24298A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).